Somatic mutation profile of tumor specimen TARGET-20-PARPLC-03A (aliquot TARGET-20-PARPLC-03A-01D) from TARGET case TARGET-20-PARPLC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.1 years (2,587 days).
Specimen TARGET-20-PARPLC-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab9c08a5-1d8e-4891-8587-97103cb7ede0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARPLC-14A (Bone Marrow Normal), aliquot TARGET-20-PARPLC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c09aa3c-dec0-4a04-ac19-aa78f72e2f6b

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Frame Shift Ins 1, In Frame Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.197_198insTTT p.V66_A67insL | In Frame Ins (INS) | VAF 22/106 reads (21%) | catalogued as COSV101122450, COSV67152785; called by mutect2, pindel, varscan2
- EEF1A1 | c.450_451insAC p.G151Tfs*39 | Frame Shift Ins (INS) | VAF 32/117 reads (27%) | called by mutect2, pindel, varscan2
- SALL1 | c.2862C>T p.S954= | Silent (SNP) | VAF 45/244 reads (18%) | catalogued as rs775808496, COSV51754492; called by muse, mutect2, varscan2
- NPM1 | c.*43_*44del | 3'UTR (DEL) | VAF 14/93 reads (15%) | called by mutect2, pindel*
